Somatic mutation profile of tumor specimen C3N-00957-01 (aliquot CPT0089720009) from CPTAC case C3N-00957, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.2 years (27,089 days).
Specimen C3N-00957-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16712724-ef1d-42ba-82fe-d4b5faaf8460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00957-31 (Blood Derived Normal), aliquot CPT0091380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e41947f0-ea64-42fa-8df4-338c413a30a8

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 5, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 25/386 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 39/382 reads (10%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCL21 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1453433779; called by muse, mutect2
- CLHC1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 16/364 reads (4%) | catalogued as rs1161370277; called by muse, mutect2
- CROCC2 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs889297637; called by muse, mutect2
- CSMD3 | c.4408C>T p.R1470* (on ENST00000297405 / NM_001363185.1; = p.R1366* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 23/456 reads (5%) | catalogued as COSV52262902; called by muse, mutect2
- CUX2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55628920; called by muse, mutect2
- LRRC4C | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV53421396; called by muse, mutect2
- MED12L | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56368485, COSV99853076; called by muse, mutect2
- MKI67 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as rs921602539; called by muse, mutect2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2
- SYNE1 | c.25085C>T p.T8362M (on ENST00000367255 / NM_182961.4; = p.T8314M on NM_033071.3) | Missense Mutation (SNP) | VAF 25/502 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs147814237; ClinVar: uncertain significance; called by muse, mutect2
- TAF1L | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1183499757, COSV54256582, COSV99645119; called by muse, mutect2
- ASCL4 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2
- CDC42EP3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- DUSP13 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHB3 | c.2613G>A p.M871I | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- EPPK1 | c.5936G>A p.R1979K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- GOSR1 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HIGD1C | c.262A>T p.R88* | Nonsense Mutation (SNP) | VAF 13/350 reads (4%) | called by muse, mutect2
- KCNMA1 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 16/564 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- LAMA5 | c.2698A>G p.N900D | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- NALCN | c.5032C>A p.P1678T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- NHSL1 | c.2135T>A p.L712Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH7 | c.2258T>G p.V753G | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCLO | c.2500C>G p.P834A | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.173); called by muse, mutect2
- PLCD1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 35/663 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- RESP18 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); called by muse, mutect2
- SRP54 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.165); called by muse, mutect2
- TMEM200A | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- TPH1 | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS35L | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- ADGRV1 | c.5739C>T p.L1913= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as rs1445702123, COSV67997984; ClinVar: uncertain significance; called by muse, mutect2
- ATP8A2 | c.3462C>T p.G1154= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1459224883; called by muse, mutect2, varscan2
- IGHM | c.450C>T p.R150= | Silent (SNP) | VAF 46/540 reads (9%) | catalogued as rs782262928; called by muse, mutect2
- MAEL | c.975A>G p.L325= | Silent (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- MAGEB18 | c.339G>A p.S113= | Silent (SNP) | VAF 14/277 reads (5%) | catalogued as rs1305966996, COSV57464369; called by muse, mutect2
- TES | c.426G>T p.G142= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- TRPC7 | c.1686C>T p.N562= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as rs575067864, COSV61457584; called by muse, mutect2
- BHMT | c.-30G>A | 5'UTR (SNP) | VAF 7/203 reads (3%) | catalogued as rs1288279699; called by muse, mutect2
- DMKN | c.1383+37G>T | Intron (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- SAG | c.181+60G>A | Intron (SNP) | VAF 12/315 reads (4%) | catalogued as rs771097049, COSV68592662; called by muse, mutect2
